Surgical pathology report (de-identified scan), TCGA case TCGA-EM-A3SU, project TCGA-THCA (Thyroid Carcinoma), tissue source site University Health Network, specimen TCGA-EM-A3SU-06A (Metastatic).

[page 1 of 4]
Surgical Pathology Consultation Report

Specimen(s) Received

1. Nck: right neck content; single stitch posterior; double stitch superior;
2. Lymph node: Rt paratracheal nodes
3. Parathyroid: Rt upper parathyroid QS
4. Lymph node: Lt paratracheal node
5. Thyroid: Total thyroid stitch- upper pole right
6. Parathyroid: Rt upper parathyroid #2 QS

ICD-O-3
Carcinoma, papillary, thyroid
8260/3
Site: thyroid, NOS
C73.9 4-312
40

Diagnosis

1. Metastatic papillary thyroid carcinoma: Lymph nodes, 2 of 25 (right neck) dissection specimen
2. Metastatic papillary thyroid carcinoma: Lymph node, 1 of 6 (right paratracheal) dissection specimen
3. No pathological diagnosis: Soft tissue (listed as "right upper parathyroid") biopsy
4. No pathological diagnosis: Lymph nodes, 2 (left paratracheal) dissection specimen
5. Multifocal angioinvasive papillary carcinoma, dominant widely-invasive classical variant with focal Warthin-like areas and tall cell change (<5%), 2.1 cm, right lobe; underlying chronic lymphocytic thyroiditis and mild follicular nodular disease: Thyroid
No pathological diagnosis: Parathyroids, 2, right and left perithyroidal
- Total thyroidectomy specimen
6. No pathological diagnosis: Parathyroid (right upper) biopsy

Synoptic Data

Procedure:
Received:
Specimen Integrity:
Specimen Size:

Other: Total thyroidectomy with right neck and bilateral paratracheal dissection
Fresh
Intact
Right lobe:
6.0 cm
2.3 cm
1.4 cm
Left lobe:
3.7 cm
1.7 cm

First Malignancy History		X

[page 2 of 4]
Surgical Pathology Consultation Report

0.8 cm
Isthmus +/- pyramidal lobe:
4.0 cm
0.9 cm
0.5 cm
Right neck dissection:
12.2 cm
4.5 cm
1.5 cm
Additional specimen: right paratracheal dissection
3.5 cm
1.7 cm
1.0 cm
Specimen Weight: 23.6 g
Tumor Focality: Multifocal, bilateral
Multifocal, midline (Isthmus)

----- DOMINANT TUMOR -----

Tumor Laterality: Right lobe
Tumor Size: Greatest dimension: 2.1cm
Additional dimension: 2.0 cm
Additional dimension: 1.5 cm
Histologic Type: Papillary carcinoma, classical (usual)
Papillary carcinoma, other variant: with focal Warthin-like areas (10%) and tall cell change (<5%)
Classical (papillary) architecture
Classical cytomorphology
Histologic Grade: Not applicable
Margins: Margins uninvolved by carcinoma
Distance of invasive carcinoma to closest margin: 0.1mm
Totally encapsulated
Tumor Capsule: Present, extent widely invasive
Tumor Capsular Invasion: Indeterminate
Lymph-Vascular Invasion: Not identified
Perineural Invasion: Not identified
Extrathyroidal Extension: Not identified

----- SECOND TUMOR -----

Tumor Laterality: Right lobe
Tumor Size: Greatest dimension: 1.4cm
Additional dimensions: 1.3 cm
Histologic Type: Papillary carcinoma, follicular variant
Papillary carcinoma, other: with focal tall-cell change (<5%)
Follicular architecture
Classical cytomorphology
Histologic Grade: Not applicable
Margins: Margins uninvolved by carcinoma
Distance of invasive carcinoma to closest margin: 0.1mm
Partially encapsulated
Tumor Capsule: Present, extent widely invasive
Tumor Capsular Invasion: Present, focal extent (less than 4 vessels)
Lymph-Vascular Invasion: Not identified
Perineural Invasion: Not identified
Extrathyroidal Extension: m (multiple primary tumors)
TNM Descriptors: pT2: Tumor more than 2 cm, but not more than 4 cm, limited to thyroid
pN1b: Metastases to unilateral, bilateral or contralateral cervical or superior mediastinal lymph nodes
Number of regional lymph nodes examined: 33
Number of regional lymph nodes involved: 3
Lymph Node, Extranodal Extension Not identified
Distant Metastasis (pM): Not applicable
Additional Pathologic Findings: Adenomatoid nodule(s) or Nodular follicular disease

[page 3 of 4]
Surgical Pathology Consultation Report

Thyroiditis

Parathyroid gland(s), within normal limits

Other: additional papillary microcarcinomas: 0.1 cm (isthmus) and 0.3 cm (left lobe)

*Pathologic Staging is based on AJCC/UICC TNM, . Edition

Electronically verified by:

Clinical History

Papillary thyroid carcinoma

Gross Description

1. The specimen labeled with the patient's name and as "RT neck content: Single stitch posterior colon double stitch superior", consists of a functional right neck dissection oriented with sutures as indicated. The specimen measures 12.2 cm SI x 4.5 cm AP x 1.5 cm in depth. Within the tissue are multiple lymph nodes that range from 0.2 to 1.6 cm. Lymph nodes submitted in toto as they occur from superior to inferior:

- 1A-C multiple lymph nodes, per block
- 1D-E 1 lymph node, multiple pieces
- 1F multiple lymph nodes
- 1G-H 1 lymph node, 3 pieces
- 1I multiple lymph nodes

2. The specimen labeled with the patient's name and as "RT paratracheal nodes" consists of a piece of fibroadipose tissue that measures 3.5 by 1.7 x 1.0 cm. Within the tissue are multiple lymph nodes that range from 0.5 to 1.7 cm.

- 2A multiple lymph nodes
- 2B slice from largest lymph node

3. The specimen labeled with the patient's name and as "RT upper parathyroid QS", consists of a piece of tissue that measures 0.2 x 0.1 x 0.1 cm. It is frozen for intraoperative consultation and submitted in toto.

- 3A frozen tissue resubmitted

4. The specimen labeled with the patient's name and as "LT paratracheal node", consists of a fibroadipose tissue that measures 1.7 x 1.0 x 0.3 cm. Within the tissue at 2 lymph nodes that measure 0.4 and 1.0 cm.

- 4A submitted in toto

5. The specimen labeled with the patient's name and as "Total thyroid stitch-upper pole right lobe" consists of a thyroid gland that is received oriented with a suture and weighs 23.6 g. The right lobe measures 6.0 cm SI x 2.3 cm ML x 1.4 cm AP, the left lobe measures 3.7 cm SI x 1.7 cm ML x 0.8 cm AP and the isthmus measures 4.0 cm SI x 0.9 cm ML x 0.5 cm AP. The external surfaces have fibrous adhesions and are painted with silver nitrate. No parathyroid glands or no lymph nodes are identified grossly. The right lobe contains 2 delineated, encapsulated nodules that measure 1.4 cm SI x 1.3 cm ML x 1.1 cm AP and 2.1 cm SI x 2.0 cm ML x 1.5 cm AP. The remainder of the thyroid tissue is red-brown with possible colloid nodules. Sections of each of the nodules and normal tissue are stored frozen. Representative sections of the remainder of the specimen are submitted:

- 5A-G right lobe, superior to inferior with small nodule in B and C and large nodule and E-G
- 5H isthmus
- 5I-N left lobe in toto, superior to inferior

6. The specimen labeled with the patient's name and as "RT upper parathyroid #2 QS", consists of a piece of tissue that measures 0.3 x 0.2 x 0.2 cm. It is frozen for intraoperative consultation.

- 6A frozen tissue resubmitted

Quick Section Diagnosis

3. Right upper parathyroid: Fibroadipose tissue. No evidence of thyroid or parathyroid tissue identified.

[page 4 of 4]
Surgical Pathology Consultation Report

Called at

6. Right upper parathyroid #2: Parathyroid tissue present.

Called at

Source: NCI Genomic Data Commons file 3a572318-4753-46c4-ae45-04bcd8961a1e (TCGA-EM-A3SU.DCC20FCD-7349-4F33-BE64-09E871835446.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).